TCGA case TCGA-39-5029 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2f39e89c-a8f7-4df8-a0f5-ef9990c2133c

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Dead; Days to death: 740 days (2.0 years).

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 67.7 years (24,713 days); Year of diagnosis: 2006; AJCC pathologic T: T1b; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 140 days; Days to treatment end: 211 days; Number of cycles: 4; Treatment dose: 600 mg; Prescribed dose: 150; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed; Initial disease status: Recurrent Disease; Days to treatment start: 514 days (1.4 years); Days to treatment end: 535 days (1.5 years); Number of cycles: 2; Treatment dose: 2,000 mg; Prescribed dose: 1000; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 564 days (1.5 years); Days to treatment end: 590 days (1.6 years); Treatment dose: 3,750 cGy; Course number: 1; Number of fractions: 15; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 645 days (1.8 years); Days to treatment end: 658 days (1.8 years); Number of cycles: 2; Treatment dose: 3,600 mg; Prescribed dose: 1800; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Treatment intent type: Palliative; Days to treatment start: 658 days (1.8 years); Days to treatment end: 672 days (1.8 years); Number of cycles: 2; Treatment dose: 93 mg; Prescribed dose: 46; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Treatment intent type: Palliative; Days to treatment start: 672 days (1.8 years); Days to treatment end: 672 days (1.8 years); Number of cycles: 1; Treatment dose: 1,900 mg; Prescribed dose: 1900; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Treatment intent type: Palliative; Days to treatment start: 672 days (1.8 years); Days to treatment end: 672 days (1.8 years); Number of cycles: 1; Treatment dose: 47 mg; Prescribed dose: 47; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Palliative; Days to treatment start: 700 days (1.9 years); Days to treatment end: 700 days (1.9 years); Number of cycles: 1; Treatment dose: 200 mg; Prescribed dose: 200; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Palliative; Days to treatment start: 700 days (1.9 years); Days to treatment end: 707 days (1.9 years); Number of cycles: 2; Treatment dose: 180 mg; Prescribed dose: 90; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Palliative; Days to treatment start: 707 days (1.9 years); Days to treatment end: 707 days (1.9 years); Number of cycles: 1; Treatment dose: 180 mg; Prescribed dose: 180; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab; Treatment intent type: Palliative; Days to treatment start: 707 days (1.9 years); Days to treatment end: 707 days (1.9 years); Number of cycles: 1; Treatment dose: 460 mg; Prescribed dose: 460; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab; Treatment intent type: Palliative; Days to treatment start: 707 days (1.9 years); Days to treatment end: 707 days (1.9 years); Number of cycles: 1; Treatment dose: 750 mg; Prescribed dose: 750; Prescribed dose units: mg; Route of administration: Intravenous.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 69.0 years (25,204 days); Days to diagnosis: 491 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 612 days (1.7 years); Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site.

Follow-up (2 entries)
- Day 491 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 740 days (2.0 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 192; Tobacco smoking onset year: 1958; Tobacco smoking quit year: 2006.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-39-5029-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 1.6; Shortest dimension: 0.3.
  Slide TCGA-39-5029-01A-01-TS1: Section location: Top; Percent tumor cells: 57; Percent tumor nuclei: 70; Percent normal cells: 10; Percent necrosis: 3; Percent stromal cells: 30.
  Slide TCGA-39-5029-01A-01-BS1: Section location: Bottom; Percent tumor cells: 59; Percent tumor nuclei: 70; Percent normal cells: 8; Percent necrosis: 3; Percent stromal cells: 30.
- Sample TCGA-39-5029-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-39-5029-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 1.6; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 4; Anatomic organ subdivision: L-Lower; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No.
- Drug treatment 1: Regimen number: 2.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1.
- Drug treatment 8: Regimen number: 1; Therapy regimen: Recurrence.
- Drug treatment 9: Regimen number: 1; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Stable Disease; New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: Yes; Treatment outcome at TCGA followup: Stable Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 740 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 740 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 491 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-39-5029-01A-01D-1439-01): tumor purity 0.54, ploidy 1.78, whole-genome doublings 0.
